Somatic mutation profile of tumor specimen MP2PRT-PAUUDM-TMP1-A (aliquot MP2PRT-PAUUDM-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAUUDM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.1 years (1,876 days).
Specimen MP2PRT-PAUUDM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ac1d994-95fd-4173-b802-4e19d781e791.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUUDM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUUDM-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fab78d5d-b040-4683-844d-4ce49f8bd272

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAMSAP3 | c.2285G>A p.R762Q | Missense Mutation (SNP) | VAF 52/800 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.018); catalogued as rs779477941; called by muse, mutect2
- ETV6 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 78/259 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56766690; called by muse, mutect2, varscan2
- SNTB1 | c.1057C>A p.L353I | Missense Mutation (SNP) | VAF 162/418 reads (39%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.836); catalogued as COSV67324949; called by muse, mutect2, varscan2
- CYP3A5 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.115); called by muse, mutect2
- HDX | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 147/255 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- IGHV4-59 | c.350delinsTGGC | In Frame Ins (INS) | VAF 97/122 reads (80%) | called by pindel, varscan2*
- KCNQ3 | c.753C>A p.G251= | Silent (SNP) | VAF 48/289 reads (17%) | catalogued as COSV66463564; called by muse, mutect2, varscan2
- PHF3 | c.366A>C p.S122= | Silent (SNP) | VAF 76/232 reads (33%) | called by muse, mutect2, varscan2
- TMEM143 | c.1068C>T p.A356= | Silent (SNP) | VAF 27/820 reads (3%) | catalogued as rs1472065299; called by muse, mutect2
- HTR3A | c.916+45G>A | Intron (SNP) | VAF 182/451 reads (40%) | catalogued as rs149205752; called by muse, mutect2, varscan2
